Gene-level copy-number profile of tumor specimen TCGA-EE-A2ML-06A from TCGA case TCGA-EE-A2ML, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.6 years (15,912 days).
Specimen TCGA-EE-A2ML-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.7d9bbfc4-595c-4586-8ac8-f3f93594f197.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2ML-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/76f88399-2f18-4008-9872-7e647673c5ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 6,479; copy number 2: 50,749; copy number 3: 2,342; copy number 4: 129; copy number 5: 99.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2ML-06A-11D-A191-01): tumor purity 0.62, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–1): MIR31HG.
- chr9:21,512,115–22,214,672, 20 genes: MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 99 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:165,400,922–166,339,090, 28 genes, copy number 5 (within-gene range 2–5): RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4, UCK2, AL358115.1, MIR3658, AL606495.1, RPS3AP10, RNA5SP64, FAM78B, FAM78B-AS1, AL596087.3, MIR921, AL596087.2, AL596087.1.
- chr1:167,379,108–167,914,215, 14 genes, copy number 5 (within-gene range 3–5): AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1.
- chr1:200,623,896–201,884,291, 37 genes, copy number 5 (within-gene range 3–5): DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1, AC096677.3, PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7, NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231, IPO9, MIR6739.
- chr1:235,447,190–236,065,109, 20 genes, copy number 5 (within-gene range 3–5): B3GALNT2, MTCYBP14, MTND6P14, MTND5P19, MTND4P10, MTND4LP21, MTND3P8, MTCO3P46, GNG4, FO393422.1, AL583844.1, LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 4,058. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
